Somatic mutation profile of tumor specimen BA2846D (aliquot aq-BA2846D) from BEATAML1.0 case 2004, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.1 years (27,420 days).
Specimen BA2846D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bba31fd-2603-4203-8c3e-3f9aa7c4e4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2183D (Solid Tissue Normal), aliquot aq-BA2183D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6895c3c3-5ac4-41c5-8da5-8c13a0caa90b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs761815670; called by muse, varscan2
- ADAMTS7 | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TSPAN19 | c.638del p.L213* | Frame Shift Del (DEL) | VAF 45/115 reads (39%) | called by mutect2, varscan2
- TTN | c.41312G>T p.C13771F (on ENST00000591111; = p.C6347F on NM_003319.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PCDHB6 | chr5:141156043 C>A | 3'Flank (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
